Somatic mutation profile of tumor specimen TCGA-A2-A0YH-01A (aliquot TCGA-A2-A0YH-01A-11D-A10G-09) from TCGA case TCGA-A2-A0YH, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 53.7 years (19,596 days).
Specimen TCGA-A2-A0YH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c17b2a87-f5af-40c8-b7a9-c05ab1e8f109.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0YH-10A (Blood Derived Normal), aliquot TCGA-A2-A0YH-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49e98c5c-367b-42f3-ab92-4880e9a35358

The open-access MAF lists 83 somatic variants for this specimen: 65 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 58, Silent 18, Nonsense Mutation 5, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 15/82 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC2 | c.1815G>C p.Q605H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs766157931, COSV64988913; called by muse, mutect2, varscan2
- ABL2 | c.703G>C p.E235Q (on ENST00000502732 / NM_007314.4; = p.E220Q on NM_005158.5) | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV100772627, COSV100773109; called by muse, mutect2
- BLNK | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV56410599; called by muse, mutect2
- BTAF1 | c.3913C>G p.L1305V | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as COSV56440326; called by muse, mutect2, varscan2
- CAPN13 | c.1526dup p.Y509* | Nonsense Mutation (INS) | VAF 6/60 reads (10%) | catalogued as rs1404236039; called by mutect2, pindel, varscan2
- CATIP | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV56824703; called by muse, mutect2, varscan2
- CCDC12 | c.49C>T p.R17W (on ENST00000425441 / NM_001277074.1; = p.R30W on NM_144716.5) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1290490840, COSV99437948; called by muse, mutect2, varscan2
- CCNA2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs750866939, COSV52656321; called by muse, mutect2, varscan2
- CDC25B | c.1293C>G p.I431M (on ENST00000245960 / NM_021873.3; = p.I417M on NM_004358.4) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as COSV55660120; called by muse, mutect2, varscan2
- CLTCL1 | c.1363G>T p.D455Y | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54240757; called by muse, mutect2, varscan2
- CR1 | c.4307C>G p.S1436C | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65458134, COSV65464531; called by muse, mutect2, varscan2
- DLG5 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750819054, COSV64950317; called by muse, mutect2, varscan2
- DOT1L | c.1466-1G>T p.X489_splice | Splice Site (SNP) | VAF 19/32 reads (59%) | catalogued as COSV67113956; called by muse, mutect2, varscan2
- ERLIN2 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1056464054, COSV99379870; called by muse, mutect2
- FSHR | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as rs1376736747, COSV58626201, COSV58628208; called by muse, mutect2, varscan2
- GNB3 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs782501836, COSV51836910; called by muse, mutect2, varscan2
- GPR87 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.178); catalogued as rs765905861, COSV53464477; called by muse, mutect2, varscan2
- HNRNPCL1 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as rs1166698781, COSV100509170, COSV58610947; called by muse, mutect2, varscan2
- KCNA4 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100069328; called by muse, mutect2, varscan2
- KDM5B | c.2422G>C p.E808Q | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV99351565; called by muse, mutect2
- LDB3 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as COSV99556032; called by muse, mutect2
- LPIN3 | c.41C>T p.T14M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs140565889; called by muse, mutect2, varscan2
- MET | c.1695C>G p.I565M | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV59257997; called by muse, mutect2
- MOAP1 | c.926G>C p.R309T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.785); catalogued as COSV52092629; called by muse, mutect2, varscan2
- MTSS1 | c.911C>G p.S304C | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.894); catalogued as COSV61500595; called by muse, mutect2
- NFKB1 | c.1712C>T p.S571F (on ENST00000394820 / NM_001382627.1; = p.S572F on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.02); catalogued as COSV56961610; called by muse, mutect2, varscan2
- NLGN4X | c.55G>T p.V19F | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.167); catalogued as COSV99321341; called by muse, mutect2
- NR4A1 | c.1424G>A p.C475Y | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54488303; called by muse, mutect2, varscan2
- NT5C1A | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs41264507, COSV99348198; called by muse, mutect2
- PBX1 | c.1273C>A p.H425N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV63348688; called by muse, mutect2
- PCDHA7 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV65342235, COSV65347101; called by muse, mutect2, varscan2
- PCDHGC3 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs370299433, COSV99342445; called by muse, mutect2, varscan2
- PDZRN3 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as COSV55217713, COSV99729442; called by muse, mutect2, varscan2
- PLEKHA1 | c.1162G>C p.D388H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV64569516, COSV64570553; called by muse, mutect2, varscan2
- POLR2H | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55604849; called by muse, mutect2, varscan2
- POSTN | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.39); catalogued as rs1163613650, COSV101123500, COSV101123530; called by muse, mutect2
- PSMA3 | c.344G>C p.R115T | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV53618645; called by muse, mutect2, varscan2
- PTPRG | c.253C>G p.P85A | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55665661; called by muse, mutect2, varscan2
- RABEPK | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99413658; called by muse, mutect2, varscan2
- RIMS2 | c.1783C>T p.R595* (on ENST00000666250 / NM_001348490.2; = p.R403* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 23/258 reads (9%) | catalogued as COSV51730614; called by muse, mutect2
- RIMS2 | c.2671G>T p.D891Y (on ENST00000666250 / NM_001348490.2; = p.D699Y on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/387 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99209692; called by muse, mutect2
- RTN4R | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV50383837; called by muse, varscan2
- RXFP1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1439685174, COSV57054936, COSV57057597; called by muse, mutect2, varscan2
- SDCBP | c.776C>G p.S259* | Nonsense Mutation (SNP) | VAF 42/448 reads (9%) | catalogued as COSV99233567; called by muse, mutect2
- SENP6 | c.1471C>G p.L491V | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59195310; called by muse, mutect2, varscan2
- SEPTIN14 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101193293, COSV66431834; called by muse, mutect2, varscan2
- SLITRK5 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs756966467, COSV61527121; called by muse, mutect2, varscan2
- SOGA1 | c.2147G>T p.R716L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52919928, COSV99415864; called by muse, mutect2, varscan2
- STAP1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as rs779311728, COSV55327947; called by muse, mutect2, varscan2
- STAU2 | c.788G>A p.R263H (on ENST00000524300 / NM_001164380.2; = p.R231H on NM_014393.2) | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs780316559, COSV63312599; called by muse, mutect2, varscan2
- SUZ12 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV59497767; called by muse, mutect2, varscan2
- SYNE1 | c.19816C>A p.Q6606K (on ENST00000367255 / NM_182961.4; = p.Q6535K on NM_033071.3) | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV55124685; called by muse, mutect2, varscan2
- TBC1D8B | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV52184205; called by muse, mutect2, varscan2
- TMEM242 | c.425G>C p.*142Sext*5 | Nonstop Mutation (SNP) | VAF 31/156 reads (20%) | catalogued as COSV68826861; called by muse, mutect2, varscan2
- TTN | c.61916G>A p.R20639K (on ENST00000591111; = p.R13215K on NM_003319.4) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | PolyPhen probably damaging (0.987); catalogued as COSV60398434; called by muse, mutect2, varscan2
- USP25 | c.682C>G p.L228V | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53491212; called by muse, mutect2, varscan2
- ZDHHC5 | c.2087C>T p.T696M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs766814291, COSV54705599; called by muse, mutect2, varscan2
- ZFHX4 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV51500470; called by muse, mutect2, varscan2
- ZFHX4 | c.10767T>A p.D3589E | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.917); catalogued as COSV51500484; called by muse, mutect2, varscan2
- ZGRF1 | c.5566G>T p.E1856* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV71393921; called by muse, mutect2, varscan2
- GNE | c.1775C>G p.S592C (on ENST00000396594 / NM_001128227.3; = p.S561C on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2
- RABGGTA | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.136); called by muse, mutect2
- TRAV1-1 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- ADAP1 | c.231G>A p.G77= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV56218169; called by muse, mutect2, varscan2
- ADH5 | c.108A>C p.R36= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV99596409; called by muse, mutect2
- ATXN2L | c.1797G>A p.K599= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV57380204; called by muse, mutect2, varscan2
- C1S | c.348T>C p.N116= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as COSV100196808; called by muse, mutect2
- COL12A1 | c.4296G>C p.V1432= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as COSV59410006; called by muse, mutect2, varscan2
- DNAJC13 | c.2760G>A p.L920= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV99608289; called by muse, mutect2
- GANAB | c.1545C>A p.P515= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100648249; called by muse, mutect2
- GPR75 | c.660C>G p.V220= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV61833110; called by muse, mutect2, varscan2
- HIP1 | c.2469C>A p.I823= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100418247; called by muse, mutect2
- KDM4C | c.690A>T p.P230= | Silent (SNP) | VAF 33/200 reads (17%) | catalogued as COSV67194279; called by muse, mutect2, varscan2
- MTA3 | c.477C>T p.D159= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV68136989; called by muse, mutect2, varscan2
- OR5T2 | c.63T>A p.S21= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV57591481; called by muse, mutect2, varscan2
- PSG1 | c.465C>T p.N155= | Silent (SNP) | VAF 43/121 reads (36%) | catalogued as COSV54958734; called by muse, mutect2, varscan2
- SORL1 | c.2526C>T p.L842= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV52748738; called by muse, mutect2, varscan2
- TJP1 | c.4593A>G p.P1531= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as rs200615605; called by muse, mutect2, varscan2
- TRPV2 | c.1914C>G p.L638= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV58431142; called by muse, mutect2, varscan2
- VAMP7 | c.393C>T p.A131= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as COSV52903267; called by muse, mutect2, varscan2
- WDFY3 | c.8811G>A p.E2937= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs754743766, COSV55715955; called by muse, varscan2
